Somatic mutation profile of tumor specimen MMRF_2224_1_BM_CD138pos (aliquot MMRF_2224_1_BM_CD138pos_T1_KHS5U_L11027) from MMRF case MMRF_2224, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,649 days).
Specimen MMRF_2224_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 642b6811-2054-4adf-b35f-b3a3ee19be59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2224_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2224_1_PB_WBC_C2_KHS5U_L11028; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a847c1fb-c213-4f3a-9f77-b512daabcdac

The open-access MAF lists 82 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 21, Intron 10, Silent 8, Nonsense Mutation 5, 5'UTR 2, RNA 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-14_465del p.X153_splice | Splice Site (DEL) | VAF 24/114 reads (21%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADIPOQ | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199646033, COSV57859674; called by muse, mutect2, varscan2
- AKAP9 | c.4994A>T p.Q1665L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs763089587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM4 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs1413340341; called by muse, mutect2, varscan2
- FSTL5 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1324953520; called by muse, mutect2, varscan2
- IGDCC3 | c.2318C>T p.T773M | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs752264561; called by muse, mutect2, varscan2
- IGLV3-1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as rs555443658; called by muse, varscan2
- IGLV5-45 | c.200A>T p.Y67F | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.089); catalogued as rs563700456; called by muse, varscan2
- IGLV5-45 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs773575221; called by muse, varscan2
- IL20RB | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440568807; called by muse, mutect2, varscan2
- NFKBIA | c.735_736del p.R245Sfs*39 | Frame Shift Del (DEL) | VAF 76/256 reads (30%) | catalogued as rs1366062698; called by pindel, varscan2
- NFKBIA | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 92/224 reads (41%) | catalogued as COSV53751859, COSV53755096; called by muse, mutect2, varscan2
- NID2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs776877352; called by muse, mutect2, varscan2
- SPI1 | c.209T>A p.F70Y | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99908850; called by muse, mutect2, varscan2
- STAB1 | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs552960331, COSV100401547; called by muse, mutect2, varscan2
- SYAP1 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1214011085; called by muse, mutect2, varscan2
- TRAF3 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 46/60 reads (77%) | catalogued as COSV61026966; called by muse, mutect2, varscan2
- UNC13A | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs950847565, COSV53195450; called by muse, mutect2, varscan2
- ADCY10 | c.2642A>C p.K881T | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- CD200R1L | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL1 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DPM2 | c.70_71insGT p.Y24Cfs*6 | Frame Shift Ins (INS) | VAF 65/214 reads (30%) | called by mutect2, pindel, varscan2
- GPR12 | c.551A>T p.D184V | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KDM5A | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MAX | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEGF10 | c.1587C>A p.C529* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- MFNG | c.196T>C p.F66L | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- MRPL40 | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NEXMIF | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PPP1R3A | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 78/203 reads (38%) | called by muse, mutect2, varscan2
- RPGR | c.2044A>G p.T682A | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- SLC5A3 | c.1978T>C p.W660R | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLU7 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- SUZ12 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 88/187 reads (47%) | called by muse, mutect2, varscan2
- TRIP12 | c.4773T>C p.R1591= | Splice Region (SNP) | VAF 65/169 reads (38%) | called by muse, mutect2, varscan2
- ZNF385C | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF729 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM3A | c.2646T>C p.S882= | Silent (SNP) | VAF 184/446 reads (41%) | catalogued as rs751651265; called by muse, mutect2, varscan2
- NCAM2 | c.261T>C p.D87= | Silent (SNP) | VAF 74/188 reads (39%) | called by muse, mutect2, varscan2
- PDZD4 | c.276G>A p.P92= | Silent (SNP) | VAF 130/162 reads (80%) | catalogued as rs782745253; called by muse, mutect2, varscan2
- PPP1R37 | c.315C>T p.L105= | Silent (SNP) | VAF 146/316 reads (46%) | catalogued as rs950601538; called by muse, mutect2, varscan2
- PREX1 | c.771C>A p.I257= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV64255579; called by muse, mutect2, varscan2
- RBBP6 | c.513T>C p.I171= | Silent (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2
- TNRC6C | c.3633C>T p.L1211= | Silent (SNP) | VAF 82/194 reads (42%) | catalogued as rs1234287884, COSV56951082; called by muse, mutect2, varscan2
- TTC22 | c.549G>A p.A183= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs749194803; called by muse, mutect2, varscan2
- ACKR2 | c.*1617T>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- AFG1L | c.*1307A>G | 3'UTR (SNP) | VAF 18/51 reads (35%) | called by mutect2, varscan2
- ATP2C1 | c.*342T>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- BCL11A | c.385+4063G>T | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CARNMT1 | c.*1510G>T | 3'UTR (SNP) | VAF 11/310 reads (4%) | called by muse, mutect2
- CDK2 | c.589-368T>C | Intron (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- CLK2P1 | n.616G>A | RNA (SNP) | VAF 62/138 reads (45%) | catalogued as rs1562821654; called by muse, mutect2, varscan2
- CYB5R3 | c.*1579A>G | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- DDX6 | c.-267-88A>T | Intron (SNP) | VAF 7/11 reads (64%) | catalogued as rs1293965442; called by muse, mutect2
- DSEL | c.*4042T>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- ESRRG | c.*1022G>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- FAM120AOS | c.-513C>T | 5'UTR (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- FAM13B | c.*1899A>T | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- FOXC1 | c.*161A>G | 3'UTR (SNP) | VAF 86/214 reads (40%) | called by muse, mutect2, varscan2
- GLRA2 | c.*213C>T | 3'UTR (SNP) | VAF 29/39 reads (74%) | catalogued as rs1176638190; called by muse, mutect2, varscan2
- GPR55 | c.*62C>T | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.*383A>G | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs2529314; called by muse, varscan2
- GTPBP1 | c.*561G>A | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- HMGA2 | c.282+1382A>G | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- HS3ST5 | c.*552A>G | 3'UTR (SNP) | VAF 67/130 reads (52%) | catalogued as rs1475012165; called by muse, mutect2, varscan2
- LMAN1 | c.*3106A>G | 3'UTR (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- MAST2 | c.1780+167G>A | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- NPM1 | c.771+58T>G | Intron (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- NR2F1 | c.-1470_-1468dup | 5'UTR (INS) | VAF 6/18 reads (33%) | catalogued as rs879835171; called by mutect2, varscan2
- PAK2 | c.*1068A>G | 3'UTR (SNP) | VAF 14/129 reads (11%) | catalogued as rs1244261945; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-68105C>A | Intron (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- PLEKHB1 | c.351-159G>A | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2
- PMVK | c.*103del | 3'UTR (DEL) | VAF 69/204 reads (34%) | catalogued as rs1439033282; called by mutect2, pindel, varscan2
- PPY2P | n.10G>A | RNA (SNP) | VAF 14/31 reads (45%) | catalogued as rs1446713816; called by muse, mutect2, varscan2
- RASSF8 | chr12:26070348 A>C | 3'Flank (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- SLC24A1 | c.*471T>C | 3'UTR (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- SNX1 | c.808-18_808-15del | Intron (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- ST6GALNAC3 | c.*578C>T | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- TATDN3 | c.*948A>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- TRDN | c.484+1772T>C | Intron (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*3960A>G | 3'UTR (SNP) | VAF 18/41 reads (44%) | catalogued as rs1289713839; called by muse, mutect2, varscan2
